Surgical pathology report (de-identified scan), TCGA case TCGA-VM-A8CF, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Huntsman Cancer Institute, specimen TCGA-VM-A8CF-01A (Primary Tumor).

[page 1 of 5]
Pathology Surgical Pathology Request

Temporary Copy

Page 1 of 2

Case

Collected

Ordered by

Patient

Is

Location

ACCESSION

Submitting Physician

Clinical History

This woman presents with a left frontal brain tumor.

Diagnosis

1. BRAIN, LEFT FRONTAL LOBE, "MIDLINE TUMOR", SPECIMEN #1, RESECTION : ANAPLASTIC ASTROCYTOMA, WHO GRADE III (SEE COMMENTS).
2. BRAIN, LEFT FRONTAL LOBE, "MIDLINE BRAIN TUMOR," SPECIMEN #2, RESECTION : ANAPLASTIC ASTROCYTOMA, WHO GRADE III (SEE COMMENTS).
3. BRAIN, LEFT FRONTAL LOBE, "POST MRI MIDLINE BRAIN TUMOR", SPECIMEN #3, RESECTION : ANAPLASTIC ASTROCYTOMA, WHO GRADE III (SEE COMMENTS).

I certify that I personally conducted the diagnostic evaluation on the above specimens and have rendered the above diagnosis(es):

electronic signature

ICD-O-3
Astrocytoma, grade III 94013
Site ^{copy} Brain, supratentorial NOS
~~site~~ Brain, frontal lobe C71.0
C71.1
QW 11/27/13

For questions regarding this case, call

Comments

Sections of this tumor are referred for EGFR amplification and 1p/19q chromosome evaluation by fluorescence in-situ hybridization techniques as well as a PCR-based MGMT methylation assay. These results will be reported in an addendum when available.

Frozen Section Diagnosis

Frozen section diagnosis per 1FA - "Brain, left frontal, biopsy:
Infiltrating astrocytoma, low grade."

Gross Description

This case has three parts to it, each labeled with the patient's name and medical record number.

Part one is received fresh for intraoperative frozen section, labeled "midline tumor", and consists of a 1.8 x 1.4 x 0.5 cm aggregate of pink gelatinous tissue fragments. Representative tissue is submitted for frozen section and subsequently for permanents in cassette 1FA. The remainder of the specimen is entirely submitted for permanents in cassette 1A.

Part two is received in formalin, labeled "midline brain tumor", and consists of a 2.2 x 1.9 x 0.25 cm aggregate of pink soft tissue fragments. The specimen is entirely submitted in cassette 2A.

Part three is received in formalin, labeled "post MRI midline brain tumor", and consists of a 4.4 x 2.9 x 2.2 cm aggregate of tan soft tissue. Representative sections are submitted in cassettes 3A-3D.

[page 2 of 5]
Pathology Surgical Pathology Request

Temporary Copy

Page 2 of 2

Case #

Collector

Ordered by

Microscopic Examination

Sections of all specimens are similar and will be described together. They demonstrate a glial, infiltrative tumor of marked hypercellularity. The nuclei contain moderate pleomorphism and hyperchromasia and scattered mitoses are seen. Many of the nuclei display round profiles, but many others are angular in contour. There is no microvascular proliferation or necrosis identified in the neoplasm.

Immunohistochemistry for glial fibrillary acidic protein is diffusely positive in the tumor. MIB-1 is positive in approximately 20% of nuclei. IDH-1 is diffusely positive in the tumor, therefore, the tumor is likely to be mutated for IDH-1. Both p53 and PTEN immunostains are diffusely positive. All controls are appropriate.

This test was developed and its performance characteristics determined by .

The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use. The results are not intended to be used as the sole means for clinical diagnosis or patient management decisions.

Synoptic Report

Specimen type/procedure: Resection.

Specimen handling: Squash/Frozen Section/Permanent Sections.

Laterality: Left.

Tumor site: Brain, frontal lobe.

Histologic type and grade: Anaplastic astrocytoma, WHO Grade III.

Histologic Grade: WHO Grade III.

Margins: Cannot be assessed.

[page 3 of 5]
Addendum Report

Temporary Copy

Page 1 of 2

Case #
Collected
Ordered by

Patient
ID
Location

ACCESSION

Addendum Discussion

IMMUNOFLUORESCENCE FOR EGFR GENE AMPLIFICATION BY FISH : NON-AMPLIFIED.

EGFR/CEP7 Ratio 1.04
EGFR Copy Number (Average) 2.90

This result has been reviewed and approved by

INTERPRETIVE DATA:

Fluorescence in situ hybridization (FISH) analysis for EGFR gene amplification was performed on a section from a paraffin embedded tissue block labeled using the EGFR/CEP 7 Dual Color Probe. 40 nuclei were evaluated from regions of tumor identified on histopathologic review of a matching hematoxylin and eosin stained section. All controls worked appropriately.

EGFR gene amplification (EGFR/CEP7 ratio greater than 2.0) has been observed in a variety of tumor types, including non-small cell lung carcinomas and high grade gliomas. Detection of EGFR amplification may be useful for selection of targeted therapies.

Analyte specific reagents (ASR) are used in many laboratory tests necessary for standard medical care and generally do not require U.S. Food and Drug Administration (FDA) approval or clearance. This test was developed and its performance characteristics determined by The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use. The results are not intended to be used as the sole means for clinical diagnosis or patient management decisions. This test should not be regarded as investigational or for research use.

IMMUNOFLUORESCENCE FOR 1p/19q FISH : 1p/19q NOT DELETED.

Calculated 1p/1q ratio = 0.89 (<0.74 is deleted).
Calculated 19q/19p ratio = 1.01 (<0.88 is deleted)

This result has been reviewed and approved by

INTERPRETIVE DATA:

Fluorescence in-situ hybridization (FISH) analysis for deletions of 1p and/or 19q was performed on a section from a paraffin embedded tissue block labeled 2A" using the 1p36 / 1q25 and 19p13 / 19q13 Dual Color Probe sets. 40 nuclei were evaluated from regions of tumor identified on histopathologic review of a matching hematoxylin and eosin stained section. All controls worked appropriately.

Several retrospective studies have reported that combined 1p/19q loss or isolated 1p loss is associated with longer patient survival. A 19q solitary deletion may suggest a favorable prognosis in a smaller subset of tumors.

Analyte specific reagents (ASR) are used in many laboratory tests necessary for standard medical care and generally do not require U.S. Food and Drug Administration (FDA) approval or clearance. This test was developed and its

[page 4 of 5]
Addendum Report

Temporary Copy

Page 2 of 2

Case #

Collector

Ordered by

Patient

For all

performance characteristics determined by The U.S. Food and Drug Administration has not approved or cleared this test; however, FDA clearance or approval is not currently required for clinical use. The results are not intended to be used as the sole means for clinical diagnosis or patient management decisions. This test should not be regarded as investigational or for research use.

I certify that I personally conducted the diagnostic evaluation on the above specimen(s) and have rendered the above diagnosis(es):

electronic signature

[page 5 of 5]
Addendum Report
Temporary Copy

Page 1 of 1

Case#
Collected
Ordered by

Patient
ID
Location

ACCESSION

Addendum Discussion

MGMT METHYLATION ASSAY : GENE METHYLATION DETECTED.

MGMT Methylation Assay was performed on sections from block "1A" by . in
The results of this assay are reported below:

MGMT Methylation Assay:

Result: Gene Methylation DETECTED.
Methylation Score: 9.46

--REFERENCE VALUE--
unmethylated <2.00
methylated >=2.00

Background:

MGMT [O(6)-methylguanine-DNA methyltransferase] is a DNA repair enzyme that is involved in the repair of damage caused by a variety of DNA crosslinking compounds, including alkylating agents. Increased methylation of the MGMT gene promotor region causes diminished or silenced expression of the gene, making cells more sensitive to DNA damage. This relationship has been shown for glioblastomas and alkylating agents such as temozolomide. Approximately 40-50% of glioblastomas exhibit MGMT gene methylation. Retrospective studies have shown that detection of MGMT promotor methylation in tumor samples is associated with an increased likelihood of a favorable response to temozolomide.

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimens. Molecular analysis of the MGMT gene is performed by methylation-specific PCR and detected on ABI7900. The MGMT and beta-Actin copy numbers are used to calculate the ratio of MGMT/beta-Actin x1000. Molecular-based testing is highly accurate, but as in any laboratory test, rare diagnostic errors may occur. Results of this test are for Investigational Purposes Only. The performance characteristics of this assay have been determined by . The result should not be used as a diagnostic procedure without confirmation of the diagnosis by another medically established diagnostic product or procedure.

I certify that I personally conducted the
diagnostic evaluation on the above specimen(s)
and have rendered the above diagnosis(es):

electronic signature

Interviewer Initials:	BTG	Date Reviewed: 10/23/2013

Source: NCI Genomic Data Commons file ccb46c4b-991f-42eb-b2a1-b545a3cab707 (TCGA-VM-A8CF.3D01CE9E-83E3-4D46-A3C2-43D63BAE212B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).